Somatic mutation profile of tumor specimen TCGA-EJ-8469-01A (aliquot TCGA-EJ-8469-01A-11D-2395-08) from TCGA case TCGA-EJ-8469, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 46.6 years (17,014 days).
Specimen TCGA-EJ-8469-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9ad1f1ba-4aa2-4991-a0f2-70504d8d7281.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-8469-10A (Blood Derived Normal), aliquot TCGA-EJ-8469-10A-01D-2395-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/77ea44b7-e775-41f1-8f32-208627356cee

The open-access MAF lists 27 somatic variants for this specimen: 21 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 5, 5'UTR 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC9 | c.911G>A p.R304H | Missense Mutation (SNP) | VAF 48/147 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs770829231, COSV53969917; called by muse, mutect2, varscan2
- AGFG1 | c.526G>A p.G176S | Missense Mutation (SNP) | VAF 25/214 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs745804768, COSV59511984; called by muse, mutect2, varscan2
- CATSPERG | c.2000T>G p.V667G | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); catalogued as COSV53048740; called by muse, mutect2, varscan2
- CDC14B | c.1052C>T p.S351L | Missense Mutation (SNP) | VAF 15/177 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV55788170; called by muse, mutect2
- CES4A | c.749C>T p.A250V | Missense Mutation (SNP) | VAF 71/114 reads (62%) | SIFT tolerated (0.24); PolyPhen benign (0.262); catalogued as rs757613890, COSV58653381; called by muse, mutect2, varscan2
- CPXM1 | c.2177T>C p.L726P | Missense Mutation (SNP) | VAF 7/162 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); catalogued as COSV66045398; called by muse, mutect2
- DNAH17 | c.1342G>A p.V448M | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.25); PolyPhen benign (0.208); catalogued as rs376498268, COSV101103075; called by muse, mutect2, varscan2
- EIF2AK3 | c.365A>G p.N122S | Missense Mutation (SNP) | VAF 105/253 reads (42%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.985); catalogued as rs1331657578, COSV57547608; called by muse, mutect2, varscan2
- GRB2 | c.446G>A p.R149Q | Missense Mutation (SNP) | VAF 8/125 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.066); catalogued as rs745504425, COSV57304566; called by muse, mutect2
- HIF3A | c.1223G>A p.R408H (on ENST00000377670 / NM_152795.4; = p.R339H on NM_022462.4) | Missense Mutation (SNP) | VAF 25/194 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.813); catalogued as rs761404329, COSV52198412; called by muse, mutect2, varscan2
- ITGA9 | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 86/219 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.129); catalogued as rs201919539, COSV53242240; called by muse, mutect2, varscan2
- KIAA0753 | c.2010-1G>A p.X670_splice | Splice Site (SNP) | VAF 49/143 reads (34%) | catalogued as rs748258352, COSV63234728; called by muse, mutect2, varscan2
- MUC17 | c.3608C>T p.T1203I | Missense Mutation (SNP) | VAF 20/727 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.351); catalogued as COSV60288486; called by muse, mutect2
- PCDHGC5 | c.694G>A p.V232M | Missense Mutation (SNP) | VAF 109/273 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777780708, COSV52752070; called by muse, mutect2, varscan2
- PRKCQ | c.1571G>T p.G524V | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54111343; called by muse, mutect2
- PTPRG | c.755A>G p.Y252C | Missense Mutation (SNP) | VAF 7/186 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55641563; called by muse, mutect2
- RECQL4 | c.785G>A p.R262Q | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0.02); catalogued as rs781569277, COSV52879453; ClinVar: uncertain significance; called by muse, mutect2
- SOX7 | c.298C>T p.R100W | Missense Mutation (SNP) | VAF 58/82 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58730803; called by muse, mutect2, varscan2
- SPINK4 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 8/175 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.808); catalogued as COSV65687992; called by muse, mutect2
- TTN | c.19004T>C p.V6335A (on ENST00000591111; = p.V5408A on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 197/530 reads (37%) | PolyPhen benign (0.017); catalogued as COSV60061473; called by muse, mutect2, varscan2
- FBN1 | c.2309dup p.L771Tfs*7 | Frame Shift Ins (INS) | VAF 62/181 reads (34%) | called by mutect2, pindel, varscan2
- ABCC5 | c.2994C>T p.I998= | Silent (SNP) | VAF 25/83 reads (30%) | catalogued as rs1366518714, COSV55590161; called by muse, mutect2, varscan2
- FAT3 | c.1461G>A p.V487= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as rs1395543308, COSV53110054; called by muse, mutect2, varscan2
- HGS | c.423C>A p.V141= | Silent (SNP) | VAF 17/188 reads (9%) | catalogued as COSV61267908; called by muse, mutect2
- SLC4A1 | c.81C>T p.P27= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as rs771695604, COSV52260054; called by muse, mutect2, varscan2
- SV2C | c.654A>G p.K218= | Silent (SNP) | VAF 158/427 reads (37%) | catalogued as COSV59220078; called by muse, mutect2, varscan2
- RFC4 | c.-1C>A | 5'UTR (SNP) | VAF 11/214 reads (5%) | catalogued as COSV99960907; called by muse, mutect2
